Gene-level copy-number profile of tumor specimen HCM-BROD-0035-C49-06A from HCMI case HCM-BROD-0035-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Bone, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 9.8 years (3,585 days).
Specimen HCM-BROD-0035-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15ade59b-eca6-42b4-9e24-8d788fd01ea7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0035-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/271c727e-c09b-44b6-9baf-76368314762d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,687; copy number 2: 57,068; copy number 3: 6; copy number 4: 17; copy number 5: 23; copy number 6: 56; copy number 7: 46; copy number 8: 10; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:44,103,306–44,155,301, 8 genes, copy number 6 (within-gene range 2–6): KRT8P47, RN7SL479P, KLF17, AL356653.1, KLF18, AL359839.1, Y_RNA, OOSP1P1.
- chr1:171,137,740–171,161,568, 1 gene, copy number 7: FMO6P.
- chr1:188,218,400–188,220,676, 1 gene, copy number 7: AL596211.1.
- chr2:103,494,241–103,529,261, 2 genes, copy number 7: CRLF3P1, AC018880.1.
- chr2:131,647,990–131,767,404, 4 genes, copy number 7 (within-gene range 2–7): C2orf27A, NBEAP2, TOMM40P4, CDRT15P4.
- chr2:218,034,960–218,090,581, 2 genes, copy number 6: RUFY4, CXCR2P1.
- chr4:3,441,968–3,501,473, 2 genes, copy number 8: HGFAC, DOK7.
- chr4:70,028,455–70,085,290, 3 genes, copy number 7: HTN3, HTN1, CSN1S2AP.
- chr5:8,614,356–8,660,059, 4 genes, copy number 7: AC091953.5, MTND6P2, MTCYBP37, AC091953.2.
- chr5:10,137,138–10,171,214, 3 genes, copy number 7: AC034229.1, AC034229.6, AC034229.5.
- chr5:28,614,613–28,654,531, 2 genes, copy number 5: AC109472.1, RNU6-909P.
- chr5:168,486,451–168,530,634, 2 genes, copy number 6: RARS1, FBLL1.
- chr5:170,140,664–170,199,141, 2 genes, copy number 5: KRT18P41, LINC01187.
- chr5:176,707,356–176,743,871, 3 genes, copy number 7: AC113391.1, AC113391.2, LINC01574.
- chr7:54,185,071–54,455,093, 3 genes, copy number 6–7 (within-gene range 2–7): AC092848.2, AC092848.1, LINC01445.
- chr7:64,519,878–64,583,207, 5 genes, copy number 7: ZNF680, BNIP3P42, AC016769.3, AC016769.1, AC016769.2.
- chr7:98,211,439–98,252,232, 2 genes, copy number 6: BHLHA15, TECPR1.
- chr9:33,441,156–33,449,941, 2 genes, copy number 7: AQP3, AL356218.1.
- chr9:121,444,991–121,500,027, 2 genes, copy number 6 (within-gene range 2–6): GGTA1, RN7SL187P.
- chr10:80,749,632–80,778,088, 2 genes, copy number 5: AC027673.1, FARSBP1.
- chr10:95,141,925–95,231,144, 5 genes, copy number 5: AL157834.4, AL157834.3, PAWRP1, ACSM6, AL157834.2.
- chr10:108,547,975–108,561,815, 1 gene, copy number 6: AL353740.1.
- chr10:113,751,262–113,820,590, 3 genes, copy number 7: PLEKHS1, MIR4483, AL592546.1.
- chr11:20,574,186–20,575,042, 1 gene, copy number 7: HMGB1P40.
- chr11:35,251,205–35,420,063, 1 gene, copy number 6 (within-gene range 2–7): SLC1A2.
- chr11:35,374,265–35,421,002, 2 genes, copy number 6 (within-gene range 6–7): AC090625.1, AC090625.2.
- chr11:38,498,995–38,500,186, 1 gene, copy number 8: AC021713.1.
- chr11:91,382,909–91,383,289, 1 gene, copy number 8: AP002791.1.
- chr11:122,146,522–122,152,308, 2 genes, copy number 8: MIRLET7A2, MIR100.
- chr12:48,482,498–48,570,066, 7 genes, copy number 6: C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA.
- chr12:116,368,764–116,428,318, 2 genes, copy number 6: AC079384.1, MIR4472-2.
- chr13:94,757,451–94,761,015, 2 genes, copy number 6: BRD7P5, RPL21P112.
- chr16:52,934,813–52,943,464, 2 genes, copy number 7: PHBP21, AC007346.1.
- chr16:60,357,214–60,359,480, 2 genes, copy number 7: AC018554.1, NPAP1L.
- chr18:12,040,101–12,129,764, 10 genes, copy number 6: AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1.
- chr18:58,481,247–58,629,091, 5 genes, copy number 5: ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108.
- chr19:24,146,701–24,163,425, 2 genes, copy number 5: AC073534.2, AC073534.1.
- chr20:40,685,848–40,698,616, 2 genes, copy number 8: MAFB, AL035665.1.
- chr21:25,169,431–25,361,868, 2 genes, copy number 6 (within-gene range 2–6): AP001341.1, RNA5SP489.
- chr22:43,411,196–43,513,727, 2 genes, copy number 6: MPPED1, BX546033.1.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
